Somatic mutation profile of tumor specimen TCGA-HC-7075-01A (aliquot TCGA-HC-7075-01A-11D-1961-08) from TCGA case TCGA-HC-7075, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-HC-7075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58a4a413-a73d-4086-b445-3e4178bf5e48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7075-10A (Blood Derived Normal), aliquot TCGA-HC-7075-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d608a478-0740-4e97-9621-bce5986f4986

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 2, 3'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.2465A>C p.E822A | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55883271; called by muse, mutect2, varscan2
- CLASP2 | c.4281A>G p.I1427M (on ENST00000359576; = p.I1426M on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV56283700; called by muse, mutect2, varscan2
- CLCN3 | c.1612G>C p.G538R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61627312; called by muse, mutect2, varscan2
- CSGALNACT2 | c.67T>A p.C23S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV65675727; called by muse, mutect2
- CTPS2 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV63722086; called by muse, mutect2
- DACH2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1169916424, COSV64169409; called by muse, mutect2, varscan2
- FSTL5 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.813); catalogued as COSV60198960; called by muse, mutect2, varscan2
- MAML3 | c.2858T>A p.M953K | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV72209293; called by muse, mutect2, varscan2
- NLRP14 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV55067751; called by muse, mutect2, varscan2
- PAX4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs747805740, COSV58389181; called by muse, mutect2, varscan2
- PREP | c.275T>G p.V92G (on ENST00000369110; = p.V158G on NM_002726.5) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV64870399; called by muse, mutect2, varscan2
- RBMY1E | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.444); catalogued as COSV62777109; called by mutect2, varscan2
- SLC2A9 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370374119, COSV53320451; called by mutect2, varscan2
- SLC38A4 | c.1317C>G p.I439M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.608); catalogued as COSV56968013; called by muse, mutect2, varscan2
- SP110 | c.2023C>T p.L675F | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1396764952, COSV51253069; called by muse, mutect2, varscan2
- STRN4 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54418830, COSV54421158; called by muse, mutect2, varscan2
- VCAM1 | c.507C>G p.D169E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54119745; called by muse, mutect2, varscan2
- ESCO1 | c.2311_2344del p.R771Kfs*6 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel
- IGKV3-15 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16A | c.4160_4171del p.A1387_Y1390del | In Frame Del (DEL) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- CD3G | c.492G>A p.K164= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as COSV52675048; called by muse, mutect2, varscan2
- HAPLN1 | c.681G>T p.G227= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV57148336; called by muse, mutect2, varscan2
- SYNGR1 | c.327C>T p.I109= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs1399384648, COSV53368463; called by muse, mutect2, varscan2
- TNN | c.1309C>T p.L437= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV53427382; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593285 C>T | 3'Flank (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
